CCDI case PBCIZF — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/bd41b293-fe50-4968-964e-0ee882b4178c

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Neoplasm, uncertain whether benign or malignant: ICD-O-3 morphology code: 8000/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 15.8 years (5,773 days).

Biospecimens (4 samples)
- Sample 0DU9ME: Tissue type: Tumor; Specimen type: Solid Tissue.
- Samples 0DU9MY, 0DUIXB (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DU9N8: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
